CPTAC case C3N-02818 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/55749713-adac-43a3-9929-db85f66b2c11

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1948; Vital status: Dead; Days to death: 1,224 days (3.4 years); Year of death: 2021; Country of birth: United States.

Diagnoses (1)
1. Papillary renal cell carcinoma: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 68.9 years (25,175 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G2; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,224 days (3.4 years); Progression or recurrence: yes; Days to recurrence: 664 days (1.8 years); Days to last follow up: 1,160 days (3.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.3 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (4 entries)
- Days to follow up: 431 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 684 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 984 days (2.7 years); Disease response: With Tumor.
- Days to follow up: 1,160 days (3.2 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 664 days (1.8 years).

Other clinical attributes
- Weight: 88.9 kg; Height: 172.72 cm; BMI: 29.8.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 60; Cigarettes per day: 30; Tobacco smoking onset year: 1967; Tobacco smoking quit year: 2007; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 40.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02818-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 131 mg; Time between excision and freezing: 26 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02818-21: Section location: both upper and middle pole; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3N-02818-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 119 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02818-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
